Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A42X, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A42X-02A (Recurrent Tumor).

Recurrence

FINAL DIAGNOSIS:

Collection Date:

PART 1: BLADDER PERITONEUM, BIOPSY -
BENIGN FIBROADIPOSE TISSUE AND SKELETAL MUSCLE.

PART 2: PELVIC SIDEWALL TUMOR, LEFT, EXCISION -
RECURRENT LEIOMYOSARCOMA (see comment).

PART 3: MESENTERIC TUMOR, EXCISION -
RECURRENT LEIOMYOSARCOMA (see comment).

PART 4: ABDOMINAL WALL MASS, RIGHT, EXCISION -
RECURRENT LEIOMYOSARCOMA (see comment).

PART 5: OMENTUM, OMENTECTOMY -
BENIGN OMENTAL ADIPOSE TISSUE WITH PATCHY MESOTHELIAL PROLIFERATION AND CHRONIC
INFLAMMATION.

PART 6: APPENDIX, APPENDECTOMY -
BENIGN APPENDIX WITH FIBROUS OBLITERATION OF THE LUMEN.

PART 7: PELVIC PERITONEUM, LEFT, BIOPSY -
BENIGN FIBROADIPOSE TISSUE.

ICD-0-3

Leiomyosarcoma 8890/3
Site: abdominal wall, NOS C49.4

lw
11/7/14

COMMENT:

The tumor morphology is similar to the patient's known uterine leiomyosarcoma [REDACTED]. The companion pelvic wash cytology specimen is negative for malignant cells [REDACTED].

Source: NCI Genomic Data Commons file a862167f-16ba-4d50-96d6-bb0526eb7481 (TCGA-K1-A42X.8CDB49A3-E572-4EB6-9420-0243593737BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).